CCDI case PBBKHR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b9e375d7-6473-469b-b57e-6834b829e1b0

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.1 years (2,966 days).

Biospecimens (3 samples)
- Sample 0DAS6I: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAS6J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAS6K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
